Gene-level copy-number profile of tumor specimen HTMCP-01-16-00265-01A from CGCI case HTMCP-01-16-00265, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 52.5 years (19,168 days).
Specimen HTMCP-01-16-00265-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0624ed4f-665e-494f-94d1-f5440910d724.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-16-00265-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/95aebf6f-9116-40a1-9dbd-d53ca638e299

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,905; copy number 2: 54,785; copy number 3: 1,158; copy number 4: 28; copy number 5: 2; copy number 6: 16; copy number 8: 1; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:57,828,331–57,837,046, 2 genes, copy number 11: AC023141.7, AC023141.13.
- chr9:40,121,962–40,122,540, 1 gene, copy number 6: CDRT15P14.
- chr9:64,810,865–64,811,429, 1 gene, copy number 6: BNIP3P4.
- chr10:95,141,925–95,168,425, 1 gene, copy number 6: AL157834.4.
- chr15:21,980,277–21,981,245, 1 gene, copy number 8: OR11J6P.
- chr16:32,649,193–32,788,944, 13 genes, copy number 6: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr19:44,747,705–44,760,044, 2 genes, copy number 5: BCL3, MIR8085.

Autosomal genes at a single copy (total copy number 1): 65. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
